Somatic mutation profile of tumor specimen TARGET-20-PASLYX-09A (aliquot TARGET-20-PASLYX-09A-01D) from TARGET case TARGET-20-PASLYX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,392 days).
Specimen TARGET-20-PASLYX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb62013-eea5-44c7-8309-e8eb7c85f3f3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLYX-14A (Bone Marrow Normal), aliquot TARGET-20-PASLYX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/088f3b54-cd25-488f-be03-c88efdd3d0e6

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Frame Shift Ins 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 33/75 reads (44%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- RAD21 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1563692624, COSV52059334, COSV52064993; called by muse, mutect2, varscan2
- TET2 | c.2737C>T p.Q913* | Nonsense Mutation (SNP) | VAF 20/284 reads (7%) | catalogued as rs1368725108, COSV54396875; called by muse, mutect2
- CCDC168 | c.7617G>A p.K2539= | Silent (SNP) | VAF 46/538 reads (9%) | catalogued as rs1158733887; called by muse, mutect2
